FM case AD17633 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/33dbba47-de44-4db6-b4fd-5b0d22fbbcd2

Female, 33.1 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the female genital tract; metastasis biopsied or resected from the fallopian tube. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
